Somatic mutation profile of tumor specimen TCGA-D1-A17Q-01A (aliquot TCGA-D1-A17Q-01A-11D-A12J-09) from TCGA case TCGA-D1-A17Q, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 54.8 years (20,015 days).
Specimen TCGA-D1-A17Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432266ce-d8c6-4f49-bf55-1c191cf0ce79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A17Q-10A (Blood Derived Normal), aliquot TCGA-D1-A17Q-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ef46d04-54a6-40ad-9959-ae95b586662a

The open-access MAF lists 6,823 somatic variants for this specimen: 5,404 protein-altering or splice-affecting, 1,294 silent, 125 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,543, Silent 1,294, Nonsense Mutation 707, Splice Site 88, Intron 55, Splice Region 38, RNA 25, 3'UTR 16, Frame Shift Ins 13, 5'UTR 13, 5'Flank 9, Frame Shift Del 7.

Variants (750 of 6,823; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.4541G>A p.R1514H (on ENST00000272895 / NM_173076.3; = p.R1196H on NM_015657.3) | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs28940270, CM032167, COSV55954774, COSV55980077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4338dup p.P1447Tfs*22 | Frame Shift Ins (INS) | VAF 24/50 reads (48%) | catalogued as rs781126037; ClinVar: pathogenic; called by mutect2, varscan2
- ACADS | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs746368198, CM085211, COSV54368542; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ACTC1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.847); catalogued as rs193922680, CM003400, COSV51758448; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.1891T>G p.L631V | Missense Mutation (SNP) | VAF 65/128 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62415668; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.595-1G>T p.X199_splice | Splice Site (SNP) | VAF 136/311 reads (44%) | hotspot (GDC flag); catalogued as COSV64874534, COSV64883218; called by muse, mutect2, varscan2
- BMPR2 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 103/238 reads (43%) | catalogued as rs886039673, CM1513964, COSV65808554; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKL5 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 176/360 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1555949009, COSV101184070, COSV66110788; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 17/202 reads (8%) | catalogued as rs771941724, COSV99796334; ClinVar: likely pathogenic; called by muse, mutect2
- CPOX | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 145/352 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374394802, CM970392, COSV51637936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CUL7 | c.4318C>T p.R1440* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as rs748555538, CM053195, COSV54815176; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 151/322 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, varscan2
- DNMT1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 94/500 reads (19%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as rs755995375, COSV61576496; called by muse, mutect2, varscan2
- DYNC2LI1 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 172/379 reads (45%) | catalogued as rs745930390, CM157152, COSV53182974; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EFNB1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894801, CM041289, CM127633, COSV52661376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EVC2 | c.2092C>T p.R698* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as rs781623802, COSV60391137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.6544C>T p.R2182C | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852467, CM002001, CM061754, COSV57704780; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 137/306 reads (45%) | catalogued as rs137852421, CM0910944, CM920256, COSV64271718; ClinVar: pathogenic; called by muse, varscan2
- GNAO1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1555507477, COSV52612621, COSV52621987; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 97/174 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.361); catalogued as COSV57407433; called by muse, mutect2, varscan2
- KMT2C | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 135/326 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1403418496, COSV51343575; called by muse, mutect2, varscan2
- LAMA3 | c.7828C>T p.R2610* (on ENST00000313654 / NM_198129.4; = p.R1001* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 120/273 reads (44%) | catalogued as rs768415785, CM066903, COSV52533065; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- LCA5 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 136/355 reads (38%) | catalogued as rs1182277140, COSV63971039; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MMAA | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 20/202 reads (10%) | catalogued as rs765799472, CM042745, COSV55580463; ClinVar: pathogenic; called by muse, mutect2
- MTM1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 124/286 reads (43%) | catalogued as rs132630306, CM970990, COSV60334496, COSV60334771; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 130/282 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5509G>A p.D1837N (on ENST00000358273 / NM_001042492.3; = p.D1816N on NM_000267.3) | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs771597781, COSV62199252; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as rs772994617, COSV54984261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 173/382 reads (45%) | catalogued as rs312262863, CM085622, COSV60795408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX2 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 84/198 reads (42%) | catalogued as rs61752124, CM981684, COSV63813349; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 121/303 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 83/164 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PROC | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918154, CM910317, COSV52165362; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PRX | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as rs773009397, CM152435, COSV52528807; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1008C>A p.Y336* | Nonsense Mutation (SNP) | VAF 45/101 reads (45%) | hotspot (GDC flag); catalogued as COSV64292408, COSV64294380, COSV64309461; called by muse, mutect2, varscan2
- RLIM | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs1569309776, CM151027, COSV60325995, COSV60327625; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RP2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556318633, CM033008, CM077334, COSV54460861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.530G>A p.R177Q (on ENST00000344691 / NM_001001890.3; = p.R204Q on NM_001754.5) | Missense Mutation (SNP) | VAF 225/499 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1569061762, CM093278, COSV55866469, COSV55875660, COSV55875973; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SAMHD1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 77/375 reads (21%) | catalogued as rs121434517, CM093960, COSV53430327; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.4876C>T p.R1626* | Nonsense Mutation (SNP) | VAF 137/339 reads (40%) | catalogued as rs1060503102, COSV51837686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 101/236 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039551, CM060085, CM086981, COSV55445539, COSV55457221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TPM1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs199476315, CM034586, COSV51260395; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.56008C>T p.R18670* (on ENST00000591111; = p.R11246* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 62/160 reads (39%) | catalogued as rs869312055, CM1514595, COSV59955046; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 88/216 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, varscan2
- A1BG | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.448); catalogued as rs1177776899, COSV54050496; called by muse, mutect2, varscan2
- AAAS | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs772310506, COSV52932641; called by muse, mutect2, varscan2
- AADAC | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV51758859; called by muse, mutect2, varscan2
- AADACL2 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 67/141 reads (48%) | catalogued as rs201287466, COSV62929985; called by muse, mutect2, varscan2
- AADAT | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61787066; called by muse, mutect2, varscan2
- AAMP | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV50307297; called by muse, mutect2, varscan2
- AASDHPPT | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 79/205 reads (39%) | catalogued as rs776262908, COSV53788251; called by muse, mutect2, varscan2
- ABCA1 | c.6041G>A p.R2014K | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV66065270; called by muse, mutect2, varscan2
- ABCA1 | c.791G>T p.S264I | Missense Mutation (SNP) | VAF 136/279 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV66065276; called by muse, mutect2, varscan2
- ABCA10 | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52218066; called by muse, mutect2, varscan2
- ABCA10 | c.2094C>A p.F698L | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV99287943; called by muse, mutect2
- ABCA12 | c.7400T>G p.F2467C (on ENST00000272895 / NM_173076.3; = p.F2149C on NM_015657.3) | Missense Mutation (SNP) | VAF 110/268 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55954756; called by muse, mutect2, varscan2
- ABCA12 | c.5354G>A p.G1785D (on ENST00000272895 / NM_173076.3; = p.G1467D on NM_015657.3) | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as rs112434185, COSV99788529; called by muse, mutect2, varscan2
- ABCA13 | c.6773G>T p.R2258I | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV70027305; called by muse, mutect2, varscan2
- ABCA13 | c.10079G>T p.R3360I | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as rs1441900210, COSV101447154, COSV71285638; called by muse, mutect2, varscan2
- ABCA4 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs374152623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.3853G>T p.E1285* | Nonsense Mutation (SNP) | VAF 273/615 reads (44%) | catalogued as COSV52637365; called by muse, mutect2, varscan2
- ABCA6 | c.3022G>T p.G1008* | Nonsense Mutation (SNP) | VAF 40/142 reads (28%) | catalogued as COSV52637372, COSV52642237; called by muse, mutect2, varscan2
- ABCA6 | c.1754G>T p.G585V | Missense Mutation (SNP) | VAF 172/400 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52637378; called by muse, mutect2, varscan2
- ABCA6 | c.1478A>G p.K493R | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV52637389; called by muse, mutect2, varscan2
- ABCA6 | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 123/302 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52637397, COSV52637557, COSV52641215; called by muse, mutect2, varscan2
- ABCA7 | c.5407C>T p.R1803C | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs753938488, CM166842, COSV54027368, COSV99566130; called by muse, mutect2, varscan2
- ABCA8 | c.3496C>T p.P1166S | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52198616; called by muse, mutect2, varscan2
- ABCA8 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV52198643; called by muse, mutect2, varscan2
- ABCB1 | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55948646; called by muse, mutect2, varscan2
- ABCB11 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1192578960, COSV55588431; called by muse, mutect2, varscan2
- ABCB5 | c.3430-1G>T p.X1144_splice (on ENST00000404938 / NM_001163941.2; = p.X699_splice on NM_178559.6) | Splice Site (SNP) | VAF 74/164 reads (45%) | catalogued as COSV51707181; called by muse, mutect2, varscan2
- ABCB7 | c.1774C>A p.L592I (on ENST00000373394 / NM_001271696.3; = p.L593I on NM_004299.6) | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV53719092; called by muse, mutect2, varscan2
- ABCB7 | c.1458A>C p.K486N (on ENST00000373394 / NM_001271696.3; = p.K487N on NM_004299.6) | Missense Mutation (SNP) | VAF 94/387 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53719100; called by muse, mutect2, varscan2
- ABCC11 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs758156173, COSV62322448; called by muse, mutect2, varscan2
- ABCC2 | c.2164G>A p.G722R | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64985522; called by muse, mutect2, varscan2
- ABCC9 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 160/383 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53967437; called by muse, mutect2, varscan2
- ABCC9 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV53967454; called by muse, varscan2
- ABCC9 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV53967467; called by muse, varscan2
- ABCC9 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 131/320 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53967489; called by muse, mutect2, varscan2
- ABCD3 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 163/556 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1474170733, COSV64642789; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 91/229 reads (40%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABCG1 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304552863, COSV59202798; called by muse, mutect2, varscan2
- ABCG2 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 173/398 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52945052; called by muse, mutect2, varscan2
- ABHD10 | c.828C>G p.H276Q | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV99844909; called by muse, mutect2
- ABHD13 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566381694, COSV101024054; called by muse, mutect2
- ABHD3 | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV56676127; called by muse, mutect2, varscan2
- ABHD6 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55908236; called by muse, mutect2, varscan2
- ABI1 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 124/294 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61015312; called by muse, mutect2, varscan2
- ABI2 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 131/284 reads (46%) | catalogued as COSV53691103; called by muse, mutect2, varscan2
- ABI3 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56799750; called by muse, mutect2, varscan2
- ABI3BP | c.3088G>T p.E1030* | Nonsense Mutation (SNP) | VAF 78/182 reads (43%) | catalogued as COSV52533032; called by muse, mutect2, varscan2
- ABI3BP | c.1825A>C p.I609L | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as rs200106328, COSV52533052; called by muse, mutect2, varscan2
- ABI3BP | c.1631G>T p.R544I | Missense Mutation (SNP) | VAF 125/725 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs541159520, COSV52533076; called by muse, mutect2, varscan2
- ABL2 | c.2566G>T p.G856* (on ENST00000502732 / NM_007314.4; = p.G841* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 53/121 reads (44%) | catalogued as COSV61012601; called by muse, mutect2, varscan2
- ABL2 | c.2000A>G p.K667R (on ENST00000502732 / NM_007314.4; = p.K652R on NM_005158.5) | Missense Mutation (SNP) | VAF 123/278 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV61012622; called by muse, mutect2, varscan2
- ABL2 | c.1412T>G p.F471C (on ENST00000502732 / NM_007314.4; = p.F456C on NM_005158.5) | Missense Mutation (SNP) | VAF 108/233 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61012640; called by muse, mutect2, varscan2
- ABR | c.1143G>T p.K381N (on ENST00000302538 / NM_021962.5; = p.K344N on NM_001092.5) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99347527; called by muse, mutect2
- ABRAXAS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 242/573 reads (42%) | catalogued as rs1300270870, COSV55029469; called by muse, mutect2, varscan2
- ABRAXAS2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as rs752407314, COSV53716596; called by muse, mutect2, varscan2
- ABTB2 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 164/379 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs199929350, COSV54386494; called by muse, mutect2, varscan2
- AC004922.1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.048); catalogued as rs779413485, COSV53163063; called by muse, mutect2, varscan2
- AC005324.2 | c.1013A>G p.E338G | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV100371725; called by muse, mutect2
- AC013477.1 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 146/357 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs747722860, COSV53653440; called by muse, mutect2, varscan2
- AC013477.1 | c.2642T>A p.F881Y | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as COSV53653450; called by muse, mutect2, varscan2
- AC013489.1 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.95); catalogued as COSV51550892, COSV99183875; called by muse, mutect2, varscan2
- AC013489.1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs1265060262, COSV51550247; called by muse, mutect2, varscan2
- AC090517.4 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50996313, COSV99974591; called by muse, mutect2, varscan2
- AC090517.4 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 81/208 reads (39%) | catalogued as COSV50996315, COSV51001924; called by muse, mutect2, varscan2
- AC092718.8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 258/620 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs932937369, COSV59601556; called by muse, mutect2, varscan2
- AC104389.6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 61/284 reads (21%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV57963408; called by muse, mutect2, varscan2
- AC131160.1 | c.673A>C p.N225H | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766493456, COSV57700433; called by muse, varscan2
- AC244197.3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs782634993, CM930420, COSV61711949; called by muse, mutect2, varscan2
- ACACB | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs774959869, COSV58129464, COSV58130111; called by muse, mutect2, varscan2
- ACAD9 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 113/277 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58307128, COSV58307545; called by muse, mutect2, varscan2
- ACADVL | c.336C>A p.F112L | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50035363; called by muse, mutect2, varscan2
- ACAN | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100717154; called by muse, mutect2
- ACAP2 | c.1179G>T p.E393D | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV100462251; called by muse, mutect2
- ACAT1 | c.164T>G p.F55C | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54920455; called by muse, mutect2, varscan2
- ACE2 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 125/269 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs140016715, COSV53024501; called by muse, mutect2, varscan2
- ACE2 | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 155/579 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as COSV53024512; called by muse, mutect2, varscan2
- ACE2 | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395782023, COSV53024528; called by muse, mutect2, varscan2
- ACER1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV56835182; called by muse, mutect2, varscan2
- ACLY | c.3098T>G p.F1033C | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59861765; called by muse, mutect2, varscan2
- ACO1 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV59379018; called by muse, mutect2, varscan2
- ACOT12 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs564306951, COSV56892647, COSV56894194; called by muse, mutect2, varscan2
- ACOT9 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV60537344; called by muse, mutect2, varscan2
- ACOT9 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs1469714654, COSV60537353; called by muse, mutect2, varscan2
- ACOX3 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149623650; called by muse, mutect2, varscan2
- ACSBG2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.567); catalogued as rs751060741, COSV53123875; called by muse, mutect2, varscan2
- ACSL4 | c.1821-2A>C p.X607_splice (on ENST00000340800 / NM_022977.2; = p.X566_splice on NM_004458.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 116/266 reads (44%) | catalogued as COSV61613960; called by muse, mutect2, varscan2
- ACSL4 | c.242A>C p.K81T (on ENST00000340800 / NM_022977.2; = p.K40T on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 204/468 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV61613965; called by muse, mutect2, varscan2
- ACSM1 | c.1365G>T p.K455N | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV54634546, COSV54637809; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM3 | c.1436A>C p.D479A | Missense Mutation (SNP) | VAF 290/668 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55500842, COSV99184554; called by muse, mutect2, varscan2
- ACSS1 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1433083125, COSV60219094; called by muse, mutect2, varscan2
- ACTR5 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.014); catalogued as rs1477531740, COSV54760384; called by muse, mutect2, varscan2
- ACTR6 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 65/166 reads (39%) | catalogued as rs772218213, COSV51841544; called by muse, mutect2, varscan2
- ADAL | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 31/355 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1369513169, COSV67500333; called by muse, mutect2, varscan2
- ADAM17 | c.1994-1G>A p.X665_splice | Splice Site (SNP) | VAF 92/235 reads (39%) | catalogued as COSV100176059; called by muse, mutect2
- ADAM20 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 139/337 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs529674678, COSV56454605; called by muse, mutect2, varscan2
- ADAM20 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs770014559, COSV56454619; called by muse, mutect2, varscan2
- ADAM21 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as COSV50790920; called by muse, mutect2, varscan2
- ADAM29 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100821916; called by muse, mutect2
- ADAM7 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 121/316 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs940085461, COSV51538068; called by muse, mutect2, varscan2
- ADAM8 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101291614; called by muse, mutect2
- ADAM8 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs745491527, COSV99427237; called by muse, mutect2
- ADAMTS12 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs551278824, COSV61256246; called by muse, mutect2, varscan2
- ADAMTS19 | c.935G>T p.R312I | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV50740274; called by muse, mutect2, varscan2
- ADAMTS20 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 124/288 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs141043529; called by muse, varscan2
- ADAMTS5 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs142161826, COSV99537274; called by muse, mutect2, varscan2
- ADAMTS9 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.692); catalogued as rs779284125, COSV55778559; called by muse, mutect2, varscan2
- ADAMTSL3 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 138/331 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54443016, COSV99720411; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3485C>T p.S1162L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201924123, COSV54443025; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4142T>C p.V1381A | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.197); catalogued as rs776103135, COSV54443033; called by muse, mutect2, varscan2
- ADAR | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs374300359, CM101655; called by muse, mutect2, varscan2
- ADCY2 | c.991T>G p.C331G | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57867217; called by muse, mutect2, varscan2
- ADCY3 | c.2884-2A>C p.X962_splice | Splice Site (SNP) | VAF 73/178 reads (41%) | catalogued as COSV53166274; called by muse, mutect2, varscan2
- ADCY3 | c.1533G>A p.S511= | Splice Region (SNP) | VAF 11/39 reads (28%) | catalogued as rs771095823, COSV53166282; called by muse, mutect2, varscan2
- ADCY5 | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 186/451 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs1064797296, COSV59196464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADD3 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 148/335 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV53321602; called by muse, mutect2, varscan2
- ADGRA2 | c.1976A>C p.N659T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59442479; called by muse, mutect2, varscan2
- ADGRA3 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs758572665, COSV51561845; called by muse, mutect2, varscan2
- ADGRB1 | c.2436C>A p.F812L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV60094381; called by muse, mutect2, varscan2
- ADGRB1 | c.2942C>A p.S981Y | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV60094390; called by muse, mutect2, varscan2
- ADGRB3 | c.1474T>G p.C492G | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100999923, COSV65405996; called by muse, mutect2
- ADGRD1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs377562590; called by muse, mutect2, varscan2
- ADGRD1 | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV55442436; called by muse, mutect2, varscan2
- ADGRE1 | c.2002A>G p.I668V | Missense Mutation (SNP) | VAF 59/430 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1234923851, COSV99165067; called by muse, mutect2, varscan2
- ADGRE5 | c.1736G>A p.R579H (on ENST00000242786 / NM_078481.4; = p.R486H on NM_001784.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs548189622, COSV54391077; called by muse, mutect2, varscan2
- ADGRF2 | c.2014G>A p.D672N (on ENST00000296862 / NM_001368115.2; = p.D604N on NM_153839.7) | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs144129468, COSV57286912; called by muse, mutect2, varscan2
- ADGRF5 | c.1438A>C p.I480L | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.466); catalogued as COSV51932305; called by muse, mutect2, varscan2
- ADGRG2 | c.977C>A p.S326Y (on ENST00000379869 / NM_001079858.3; = p.S323Y on NM_005756.4) | Missense Mutation (SNP) | VAF 202/469 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV61338447; called by muse, mutect2, varscan2
- ADGRG4 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV54953389; called by muse, mutect2, varscan2
- ADGRG4 | c.3842A>T p.K1281M | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV54953397; called by muse, mutect2, varscan2
- ADGRG4 | c.7362G>T p.K2454N | Missense Mutation (SNP) | VAF 154/335 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV54953404; called by muse, mutect2, varscan2
- ADGRG6 | c.1847T>A p.I616N | Missense Mutation (SNP) | VAF 114/253 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51589843; called by muse, mutect2, varscan2
- ADGRG6 | c.3649A>G p.K1217E | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99745923; called by muse, mutect2
- ADGRG7 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV56295349, COSV56297369; called by muse, mutect2, varscan2
- ADGRL2 | c.510T>G p.I170M | Missense Mutation (SNP) | VAF 97/219 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54662403; called by muse, mutect2, varscan2
- ADGRL3 | c.2287G>A p.D763N (on ENST00000506720 / NM_001322402.2; = p.D695N on NM_015236.6) | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV72230156, COSV72230410; called by muse, varscan2
- ADGRV1 | c.14443G>A p.E4815K | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1047853698, COSV67982901; called by muse, varscan2
- ADGRV1 | c.14729C>A p.S4910Y | Missense Mutation (SNP) | VAF 99/223 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV67982905; called by muse, mutect2, varscan2
- ADPGK | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as rs752942617, COSV61173705; called by muse, mutect2, varscan2
- ADRA2A | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as COSV54527450; called by muse, varscan2
- ADRA2C | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467112; called by muse, mutect2, varscan2
- ADSS2 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.808); catalogued as COSV63694868; called by muse, mutect2
- AFDN | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 219/489 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as rs765967945, COSV60042245; called by muse, mutect2, varscan2
- AFF1 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as rs1346801780, COSV57118699; called by muse, mutect2, varscan2
- AFF1 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 25/181 reads (14%) | catalogued as COSV57118705; called by muse, mutect2, varscan2
- AFF4 | c.3069G>T p.K1023N | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54793436, COSV54794344; called by muse, mutect2, varscan2
- AFG1L | c.284G>T p.R95I | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV64555284; called by muse, mutect2, varscan2
- AFM | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.637); catalogued as COSV56919694; called by muse, mutect2, varscan2
- AGAP1 | c.1936G>A p.E646K (on ENST00000304032 / NM_001037131.3; = p.E593K on NM_014914.5) | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376727493; called by muse, mutect2, varscan2
- AGAP2 | c.2507A>C p.K836T (on ENST00000547588 / NM_001122772.2; = p.K500T on NM_014770.4) | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV57727624; called by muse, mutect2, varscan2
- AGBL1 | c.3079G>T p.E1027* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | catalogued as COSV66854312; called by muse, mutect2, varscan2
- AGGF1 | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 141/322 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV57228483; called by muse, mutect2, varscan2
- AGL | c.2681C>T p.S894F | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs866082714, COSV54051116; called by muse, mutect2, varscan2
- AGO3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV55791459; called by muse, mutect2, varscan2
- AGTPBP1 | c.644A>G p.K215R | Missense Mutation (SNP) | VAF 125/271 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.059); catalogued as COSV61270385; called by muse, mutect2, varscan2
- AGTPBP1 | c.42T>G p.N14K | Missense Mutation (SNP) | VAF 87/191 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.228); catalogued as COSV61270398; called by muse, mutect2, varscan2
- AHCTF1 | c.2590C>A p.L864I (on ENST00000366508; = p.L838I on NM_015446.5) | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV58248294; called by muse, mutect2, varscan2
- AHCYL1 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 105/247 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV63208506; called by muse, mutect2, varscan2
- AHCYL1 | c.1334T>G p.L445W | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV63208512; called by muse, mutect2, varscan2
- AHI1 | c.1338C>A p.F446L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as rs770926761, COSV55626005; called by muse, mutect2, varscan2
- AHNAK | c.10252C>T p.P3418S | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs983490725, COSV57210043; called by muse, mutect2, varscan2
- AHNAK | c.4243G>T p.G1415* | Nonsense Mutation (SNP) | VAF 17/504 reads (3%) | catalogued as COSV99945793; called by muse, mutect2
- AHNAK2 | c.13486G>A p.D4496N | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs760149560, COSV60912529; called by muse, mutect2, varscan2
- AHNAK2 | c.11830A>C p.K3944Q | Missense Mutation (SNP) | VAF 144/307 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV60912536; called by muse, mutect2, varscan2
- AHR | c.2409G>T p.Q803H | Missense Mutation (SNP) | VAF 168/357 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV54122681; called by muse, mutect2, varscan2
- AIFM1 | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54853901; called by muse, mutect2, varscan2
- AIFM3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs747011410, COSV53146636; called by muse, mutect2, varscan2
- AIPL1 | c.866A>C p.K289T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV51506534; called by muse, mutect2, varscan2
- AIRE | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs202237214; called by muse, mutect2, varscan2
- AK7 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 190/396 reads (48%) | catalogued as COSV50869619; called by muse, mutect2, varscan2
- AK8 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53752866; called by muse, mutect2, varscan2
- AK8 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV53752896; called by muse, mutect2, varscan2
- AK9 | c.603A>C p.E201D | Missense Mutation (SNP) | VAF 138/533 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.356); catalogued as COSV53420752; called by muse, mutect2, varscan2
- AKAP1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1422441599, COSV58469590; called by muse, mutect2, varscan2
- AKAP11 | c.2963T>G p.F988C | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV50295290; called by muse, mutect2, varscan2
- AKAP12 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV53573061; called by muse, mutect2, varscan2
- AKAP12 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV53573073; called by muse, mutect2, varscan2
- AKAP17A | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 28/710 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs753166381, COSV100001925; called by muse, mutect2
- AKAP3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs200377453, COSV57415556; called by muse, mutect2, varscan2
- AKAP6 | c.6462C>A p.C2154* | Nonsense Mutation (SNP) | VAF 85/213 reads (40%) | catalogued as COSV55210297; called by muse, mutect2, varscan2
- AKAP7 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 29/239 reads (12%) | catalogued as rs754751702, COSV53834357; called by muse, mutect2, varscan2
- AKAP8 | c.497T>C p.F166S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54102003; called by muse, mutect2, varscan2
- AKAP9 | c.926A>C p.E309A | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV62343121; called by muse, mutect2, varscan2
- AKAP9 | c.1694T>G p.L565R | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.459); catalogued as COSV62343152; called by muse, mutect2, varscan2
- AKAP9 | c.10144C>T p.R3382C (on ENST00000359028; = p.R3358C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769113364, COSV62343165; called by muse, mutect2, varscan2
- AKAP9 | c.11716C>T p.R3906W (on ENST00000359028; = p.R3882W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370539725; called by muse, mutect2, varscan2
- AKNA | c.3262C>T p.R1088C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs143050232; called by muse, mutect2, varscan2
- AKR1C1 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 137/302 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66498942; called by muse, mutect2, varscan2
- AKR1E2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs1015552661, COSV53630001; called by muse, mutect2, varscan2
- AKT2 | c.157A>C p.N53H | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60908123; called by muse, mutect2, varscan2
- AKT3 | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 168/366 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV55613079, COSV55618127; called by muse, varscan2
- AL021546.1 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV57569238; called by muse, mutect2, varscan2
- AL133500.1 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated, low confidence (0.13); catalogued as COSV55744476; called by muse, mutect2, varscan2
- ALAS1 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1401131653, COSV59627493; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 137/342 reads (40%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH18A1 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 144/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100973071; called by muse, varscan2
- ALDH1A1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 129/315 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52790445; called by muse, mutect2, varscan2
- ALDH3B2 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62427957; called by muse, mutect2, varscan2
- ALDH7A1 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380803513, COSV101301993; called by muse, mutect2
- ALDH8A1 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 81/184 reads (44%) | catalogued as COSV55641140; called by muse, mutect2, varscan2
- ALDH9A1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 29/287 reads (10%) | catalogued as rs755173841, COSV100699297, COSV61341344; called by muse, mutect2, varscan2
- ALDOA | c.894T>G p.F298L (on ENST00000642816 / NM_001243177.4; = p.F244L on NM_184041.5) | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV57632394; called by muse, mutect2, varscan2
- ALG13 | c.2938A>T p.K980* | Nonsense Mutation (SNP) | VAF 189/410 reads (46%) | catalogued as COSV52637584; called by muse, mutect2, varscan2
- ALG5 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 56/140 reads (40%) | catalogued as COSV53504958; called by muse, mutect2, varscan2
- ALK | c.2586G>T p.E862D | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.38); catalogued as COSV66557480, COSV66563771; called by muse, mutect2, varscan2
- ALKBH1 | c.372G>T p.Q124H | Missense Mutation (SNP) | VAF 119/291 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV53659371; called by muse, mutect2, varscan2
- ALKBH8 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 18/450 reads (4%) | catalogued as COSV99508486; called by muse, mutect2
- ALMS1 | c.5568C>A p.H1856Q | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100041248; called by muse, mutect2
- ALMS1 | c.7529T>C p.V2510A | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52507340; called by muse, mutect2, varscan2
- ALMS1 | c.10928C>A p.S3643Y | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs867845702, COSV52507349; called by muse, mutect2, varscan2
- ALOX12 | c.1845C>A p.F615L | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52349344; called by muse, mutect2, varscan2
- ALOX5 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs989659749, COSV65551915; called by muse, mutect2, varscan2
- ALOXE3 | c.781A>C p.T261P | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV59075017; called by muse, mutect2, varscan2
- ALOXE3 | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.023); catalogued as rs978460024, COSV58554624; called by muse, varscan2
- ALPG | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs751216452, COSV54965664; called by muse, mutect2, varscan2
- ALPK2 | c.1522A>G p.M508V | Missense Mutation (SNP) | VAF 59/568 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV64491923; called by muse, mutect2
- ALPK2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 278/659 reads (42%) | catalogued as rs1168113815, COSV64491928; called by muse, mutect2, varscan2
- ALPK3 | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV51932128; called by muse, mutect2, varscan2
- AMACR | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV59460480; called by muse, mutect2, varscan2
- AMBRA1 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.265); catalogued as COSV54051813; called by muse, mutect2, varscan2
- AMER1 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 109/198 reads (55%) | catalogued as COSV100367055, COSV57658549; called by muse, mutect2, varscan2
- AMPD1 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62415397, COSV62415673; called by muse, mutect2, varscan2
- AMPD3 | c.218A>C p.K73T (on ENST00000396553 / NM_001025389.2; = p.K82T on NM_000480.3) | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV67330539; called by muse, mutect2, varscan2
- AMPD3 | c.1924G>A p.E642K (on ENST00000396553 / NM_001025389.2; = p.E651K on NM_000480.3) | Missense Mutation (SNP) | VAF 182/426 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.164); catalogued as rs767990716, COSV67330507; called by muse, mutect2, varscan2
- AMPH | c.226A>C p.K76Q | Missense Mutation (SNP) | VAF 79/270 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57739094; called by muse, mutect2, varscan2
- AMZ2 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 81/201 reads (40%) | catalogued as COSV63082715; called by muse, mutect2, varscan2
- ANAPC1 | c.4753C>A p.L1585I | Missense Mutation (SNP) | VAF 104/571 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.438); catalogued as COSV61975282; called by muse, mutect2, varscan2
- ANGEL1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs781056502, COSV51872668; called by muse, mutect2, varscan2
- ANGEL2 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as rs982573649, COSV64737165, COSV64737255; called by muse, varscan2
- ANGPTL1 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 116/283 reads (41%) | catalogued as COSV52365955; called by muse, mutect2, varscan2
- ANGPTL2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV52219858; called by muse, mutect2, varscan2
- ANGPTL3 | c.589A>C p.K197Q | Missense Mutation (SNP) | VAF 155/383 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV52001802; called by muse, mutect2, varscan2
- ANK2 | c.7840G>T p.E2614* | Nonsense Mutation (SNP) | VAF 115/249 reads (46%) | catalogued as COSV52155032; called by muse, mutect2, varscan2
- ANK2 | c.8063G>A p.R2688Q | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); catalogued as rs142107156, COSV52155040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.9587C>T p.S3196L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs144719173, COSV52190287; called by muse, mutect2, varscan2
- ANK3 | c.7786C>T p.R2596C | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55053162; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 56/130 reads (43%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANKFN1 | c.400A>C p.N134H | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as COSV59444815; called by muse, mutect2, varscan2
- ANKFN1 | c.1381G>T p.V461L | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100593155; called by muse, mutect2
- ANKIB1 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56060259; called by muse, mutect2, varscan2
- ANKLE2 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 29/362 reads (8%) | catalogued as COSV100513944; called by muse, mutect2
- ANKLE2 | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 206/484 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61708811; called by muse, mutect2, varscan2
- ANKRD11 | c.7163G>A p.R2388H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56358957; called by muse, mutect2
- ANKRD11 | c.4342T>C p.Y1448H | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV99968405; called by muse, mutect2
- ANKRD24 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53669316; called by muse, mutect2, varscan2
- ANKRD24 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 49/122 reads (40%) | catalogued as COSV53669344, COSV53671248; called by muse, mutect2, varscan2
- ANKRD28 | c.184T>G p.L62V | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV101080348; called by muse, mutect2
- ANKRD29 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 56/568 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99409040; called by muse, mutect2
- ANKRD30A | c.1572+1G>T p.X524_splice (on ENST00000611781; = p.X468_splice on NM_052997.2) | Splice Site (SNP) | VAF 413/903 reads (46%) | catalogued as COSV64608073; called by muse, mutect2, varscan2
- ANKRD30A | c.1615G>T p.E539* (on ENST00000611781; = p.E483* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 385/847 reads (45%) | catalogued as COSV64608080; called by muse, mutect2, varscan2
- ANKRD30A | c.1870G>A p.E624K (on ENST00000611781; = p.E568K on NM_052997.2) | Missense Mutation (SNP) | VAF 222/550 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.145); catalogued as COSV64604975, COSV99077929; called by muse, mutect2, varscan2
- ANKRD34B | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV58613731; called by muse, mutect2, varscan2
- ANKRD44 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 109/262 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56552643; called by muse, mutect2, varscan2
- ANKRD45 | c.619A>C p.K207Q | Missense Mutation (SNP) | VAF 164/355 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV60960679; called by muse, mutect2, varscan2
- ANKRD52 | c.2450C>T p.S817L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs780759590, COSV57282937; called by muse, mutect2, varscan2
- ANKRD6 | c.1766G>T p.R589I (on ENST00000339746 / NM_001242809.2; = p.R584I on NM_014942.4) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60230425; called by muse, mutect2, varscan2
- ANO3 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99880783; called by muse, mutect2, varscan2
- ANO3 | c.2455A>C p.I819L | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV56787182; called by muse, mutect2, varscan2
- ANO3 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs770630092, COSV56787191; called by muse, mutect2, varscan2
- ANO4 | c.311G>T p.R104I (on ENST00000392977 / NM_001286615.2; = p.R69I on NM_178826.4) | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54591769; called by muse, mutect2, varscan2
- ANO4 | c.2544C>A p.F848L (on ENST00000392977 / NM_001286615.2; = p.F813L on NM_178826.4) | Missense Mutation (SNP) | VAF 185/360 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV54591783; called by muse, mutect2, varscan2
- ANO7 | c.1299G>T p.W433C (on ENST00000274979; = p.W379C on NM_001370694.2) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51470441; called by muse, mutect2, varscan2
- ANOS1 | c.1474C>A p.L492M | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52917966; called by muse, mutect2, varscan2
- ANP32E | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 309/689 reads (45%) | catalogued as COSV58481775; called by muse, mutect2, varscan2
- ANP32E | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as rs782603651, COSV58481542; called by muse, mutect2, varscan2
- ANTXR2 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 163/368 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV55018037; called by muse, mutect2, varscan2
- ANXA4 | c.96C>T p.L32= | Splice Region (SNP) | VAF 73/153 reads (48%) | catalogued as rs187492712; called by muse, mutect2, varscan2
- ANXA4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs865798673, COSV67848655; called by muse, mutect2, varscan2
- AOC1 | c.725T>C p.F242S | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV62867988; called by muse, mutect2, varscan2
- AOC1 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 62/158 reads (39%) | catalogued as COSV62867995; called by muse, mutect2, varscan2
- AOX1 | c.968T>C p.V323A | Missense Mutation (SNP) | VAF 73/135 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV65980944; called by muse, mutect2, varscan2
- AOX1 | c.1877C>A p.S626Y | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65980949; called by muse, mutect2, varscan2
- AP1S3 | c.51G>T p.Q17H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57510250; called by muse, mutect2, varscan2
- AP2A1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV62817910; called by muse, mutect2, varscan2
- AP2A2 | c.1970C>T p.P657L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs915562648, COSV59959621; called by muse, mutect2, varscan2
- AP3B1 | c.2734C>T p.R912* | Nonsense Mutation (SNP) | VAF 237/615 reads (39%) | catalogued as rs752519227, COSV54877147; called by muse, mutect2, varscan2
- AP3B2 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs868273372, COSV55608398; called by muse, mutect2, varscan2
- AP3B2 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442353474, COSV55608425; called by muse, mutect2, varscan2
- AP4B1 | c.2096T>C p.L699S | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV56724322; called by muse, mutect2, varscan2
- AP4B1 | c.1174C>A p.L392I | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV56724327; called by muse, varscan2
- AP4E1 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 104/264 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs754437475, COSV55916257; called by muse, mutect2, varscan2
- AP5M1 | c.506T>C p.F169S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV55105082; called by muse, mutect2, varscan2
- APAF1 | c.575A>C p.K192T (on ENST00000551964 / NM_181861.2; = p.K181T on NM_001160.3) | Missense Mutation (SNP) | VAF 155/354 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1370484839, COSV59663141; called by muse, mutect2, varscan2
- APAF1 | c.796G>T p.D266Y (on ENST00000551964 / NM_181861.2; = p.D255Y on NM_001160.3) | Missense Mutation (SNP) | VAF 16/398 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59661498; called by muse, mutect2
- APBB1 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 124/268 reads (46%) | catalogued as COSV54974409; called by muse, mutect2, varscan2
- APBB2 | c.1846C>A p.L616I (on ENST00000295974 / NM_001166050.2; = p.L617I on NM_004307.2) | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV55950395; called by muse, mutect2, varscan2
- API5 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV66632864; called by muse, mutect2, varscan2
- API5 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 97/201 reads (48%) | catalogued as COSV66632870; called by muse, mutect2, varscan2
- API5 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs372123869; called by muse, mutect2, varscan2
- APOB | c.8416T>G p.F2806V | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51931141; called by muse, mutect2, varscan2
- APOB | c.7295A>G p.Y2432C | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51931152; called by muse, mutect2, varscan2
- APOB | c.1855C>A p.L619M | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51931163; called by muse, mutect2, varscan2
- APOBEC3A | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV50779274; called by muse, varscan2
- APOH | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV99235563; called by muse, mutect2
- AQR | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV50031771; called by muse, varscan2
- AR | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs370971743, COSV65955008; called by muse, mutect2, varscan2
- AREL1 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752826616, COSV62666047; called by muse, mutect2, varscan2
- AREL1 | c.1423-1G>A p.X475_splice | Splice Site (SNP) | VAF 72/154 reads (47%) | catalogued as COSV62666051; called by muse, mutect2, varscan2
- ARFGAP3 | c.454_455insG p.F152Cfs*8 | Frame Shift Ins (INS) | VAF 71/173 reads (41%) | catalogued as COSV99605122; called by mutect2, pindel, varscan2
- ARFGEF1 | c.3669G>T p.E1223D | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51606083; called by muse, mutect2, varscan2
- ARFGEF1 | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 133/593 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV51606096; called by muse, mutect2, varscan2
- ARFGEF1 | c.54G>T p.K18N | Missense Mutation (SNP) | VAF 83/158 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51606109; called by muse, mutect2, varscan2
- ARFGEF2 | c.5002C>T p.R1668* | Nonsense Mutation (SNP) | VAF 109/260 reads (42%) | catalogued as COSV64211634; called by muse, mutect2, varscan2
- ARGLU1 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 215/471 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65608292; called by muse, mutect2, varscan2
- ARHGAP10 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.687); catalogued as COSV60597417; called by muse, varscan2
- ARHGAP11A | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 89/183 reads (49%) | catalogued as COSV64380799; called by muse, mutect2, varscan2
- ARHGAP12 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV60962390; called by muse, mutect2, varscan2
- ARHGAP18 | c.102A>C p.E34D | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV63764077; called by muse, mutect2, varscan2
- ARHGAP19 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 104/211 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765513484, COSV57392233; called by muse, mutect2, varscan2
- ARHGAP20 | c.3197C>A p.S1066Y | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV52809325; called by muse, mutect2, varscan2
- ARHGAP21 | c.4178C>A p.S1393Y | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57604552; called by muse, mutect2, varscan2
- ARHGAP21 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 162/382 reads (42%) | catalogued as COSV57604563; called by muse, mutect2, varscan2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 38/187 reads (20%) | catalogued as rs376118883; called by muse, mutect2, varscan2
- ARHGAP25 | c.341T>G p.I114S (on ENST00000409202 / NM_001007231.3; = p.I107S on NM_014882.3) | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV54901000, COSV54908375; called by muse, mutect2, varscan2
- ARHGAP25 | c.1042A>G p.R348G (on ENST00000409202 / NM_001007231.3; = p.R340G on NM_014882.3) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV54901014; called by muse, mutect2, varscan2
- ARHGAP26 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50827340; called by muse, mutect2, varscan2
- ARHGAP29 | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs748894382, COSV53110021; called by muse, mutect2, varscan2
- ARHGAP30 | c.2948G>A p.R983Q (on ENST00000368013 / NM_001025598.2; = p.R772Q on NM_181720.3) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs376108588; called by muse, mutect2, varscan2
- ARHGAP32 | c.4867T>C p.Y1623H (on ENST00000310343 / NM_001378025.1; = p.Y1274H on NM_014715.4) | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV59845909; called by muse, mutect2, varscan2
- ARHGAP35 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.074); catalogued as COSV68330376; called by muse, mutect2, varscan2
- ARHGAP35 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs1322723304, COSV68330383, COSV68334239; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP35 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs758716231, COSV101351173, COSV68330389; called by muse, mutect2, varscan2
- ARHGAP36 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 69/176 reads (39%) | catalogued as COSV52265620; called by muse, mutect2, varscan2
- ARHGAP5 | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs142888518, COSV61533966; called by muse, mutect2, varscan2
- ARHGAP6 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 109/245 reads (44%) | catalogued as COSV100272954, COSV57294273; called by muse, mutect2, varscan2
- ARHGEF10L | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs767420688, COSV63418444; called by muse, mutect2, varscan2
- ARHGEF11 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 234/506 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs377075621; called by muse, mutect2, varscan2
- ARHGEF11 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs375264879; called by muse, mutect2, varscan2
- ARHGEF15 | c.2518C>A p.P840T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV62724840; called by muse, mutect2, varscan2
- ARHGEF17 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV55229730; called by muse, mutect2, varscan2
- ARHGEF17 | c.5477C>A p.S1826Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV55231465; called by muse, mutect2, varscan2
- ARHGEF28 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as rs779364770, COSV55252872; called by muse, mutect2, varscan2
- ARHGEF40 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53879422; called by muse, mutect2, varscan2
- ARHGEF5 | c.1207C>T p.H403Y | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1458437202, COSV50209161; called by muse, mutect2, varscan2
- ARHGEF5 | c.4750C>T p.R1584* | Nonsense Mutation (SNP) | VAF 54/124 reads (44%) | catalogued as rs750003677, COSV50209207, COSV99283095; called by muse, varscan2
- ARHGEF6 | c.1145A>C p.K382T | Missense Mutation (SNP) | VAF 187/441 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99166354; called by muse, mutect2
- ARHGEF6 | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 194/454 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99166355, COSV99166761; called by muse, mutect2
- ARID1B | c.3851C>T p.T1284M | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs371538726; called by muse, mutect2, varscan2
- ARID4A | c.2401G>T p.D801Y | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62162621, COSV62163028, COSV62164588; called by muse, mutect2, varscan2
- ARID4B | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 136/320 reads (43%) | catalogued as COSV51601401; called by muse, mutect2, varscan2
- ARL5B | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV66011115; called by muse, mutect2, varscan2
- ARL6IP4 | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.085); catalogued as COSV54898976; called by muse, mutect2, varscan2
- ARL8B | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99848495; called by muse, mutect2
- ARMCX1 | c.1061T>G p.F354C | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65705034; called by muse, mutect2, varscan2
- ARMCX5 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 103/233 reads (44%) | catalogued as COSV55766327; called by muse, mutect2, varscan2
- ARMH3 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs991447377, COSV60750691, COSV60751300; called by muse, mutect2, varscan2
- ARNTL2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 50/103 reads (49%) | catalogued as COSV53824861; called by muse, mutect2, varscan2
- ARPP19 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 244/570 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51119197; called by muse, mutect2, varscan2
- ARRDC3 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54364905; called by muse, mutect2, varscan2
- ARRDC4 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51418953; called by muse, mutect2, varscan2
- ARSF | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.528); catalogued as rs775909323, COSV63839313; called by muse, mutect2, varscan2
- ARSK | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 128/268 reads (48%) | catalogued as rs199509272, COSV66169451; called by muse, mutect2, varscan2
- ARV1 | c.626A>G p.K209R | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV59617501; called by muse, mutect2, varscan2
- ASAH1 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 184/370 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100026028, COSV50501754; called by muse, mutect2, varscan2
- ASB12 | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV62856544; called by muse, varscan2
- ASB15 | c.1443C>A p.F481L | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99306237; called by muse, mutect2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 61/151 reads (40%) | catalogued as rs1237485684, COSV51923543; called by muse, mutect2, varscan2
- ASB2 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV60111289; called by muse, mutect2, varscan2
- ASB8 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.601); catalogued as COSV100402282; called by muse, mutect2
- ASCC1 | c.350A>G p.K117R (on ENST00000342444 / NM_001369085.1; = p.K89R on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/505 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as rs757339958, COSV57726028; called by muse, mutect2, varscan2
- ASIC1 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV57317396; called by muse, mutect2, varscan2
- ASIC4 | c.1418C>A p.S473Y (on ENST00000347842 / NM_182847.3; = p.S492Y on NM_018674.6) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV61731490; called by muse, mutect2, varscan2
- ASMT | c.948C>A p.H316Q (on ENST00000381229; = p.H344Q on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 261/552 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV67109752; called by muse, mutect2, varscan2
- ASMTL | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.51); catalogued as rs759210384, COSV67243371; called by muse, mutect2, varscan2
- ASNS | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 15/283 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV99445960; called by muse, mutect2
- ASNSD1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777711639, COSV53623426; called by muse, mutect2, varscan2
- ASPM | c.8392T>C p.Y2798H | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.248); catalogued as COSV54128037; called by muse, mutect2, varscan2
- ASPN | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 171/385 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV65015955, COSV65016337; called by muse, mutect2, varscan2
- ASXL1 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60106123; called by muse, mutect2, varscan2
- ASXL2 | c.1001C>A p.S334* | Nonsense Mutation (SNP) | VAF 69/135 reads (51%) | catalogued as COSV55454395, COSV55456678; called by muse, mutect2, varscan2
- ASXL3 | c.2509A>G p.T837A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52462852; called by muse, mutect2, varscan2
- ASXL3 | c.6493A>G p.K2165E | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV99323563, COSV99323996; called by muse, mutect2
- ATAD2 | c.2976C>A p.F992L | Missense Mutation (SNP) | VAF 173/380 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV54879564; called by muse, mutect2, varscan2
- ATAD2 | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 123/299 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV54879576; called by muse, mutect2, varscan2
- ATAD2B | c.3652G>A p.G1218R | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV53197057; called by muse, mutect2, varscan2
- ATAD2B | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs780350357, COSV53197069; called by muse, varscan2
- ATAD5 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 86/184 reads (47%) | catalogued as COSV58973478; called by muse, mutect2, varscan2
- ATE1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs773450449, COSV56435136; called by muse, mutect2, varscan2
- ATF7IP | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV53768809; called by muse, mutect2, varscan2
- ATG16L1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs746840032, COSV61465102; called by muse, mutect2, varscan2
- ATG16L1 | c.1195C>T p.R399* (on ENST00000392017 / NM_030803.7; = p.R380* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 143/342 reads (42%) | catalogued as COSV61464865; called by muse, varscan2
- ATG2B | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 122/265 reads (46%) | catalogued as rs1211353744, COSV55889963; called by muse, mutect2, varscan2
- ATG2B | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1430305690, COSV63421484; called by muse, varscan2
- ATG4A | c.1127-1G>T p.X376_splice | Splice Site (SNP) | VAF 26/622 reads (4%) | catalogued as COSV57872672; called by muse, mutect2
- ATG4C | c.1058T>C p.V353A | Missense Mutation (SNP) | VAF 258/558 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58605056; called by muse, mutect2, varscan2
- ATG5 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV58347284; called by muse, mutect2, varscan2
- ATIC | c.1053G>T p.L351F | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52694481, COSV99377488; called by muse, mutect2
- ATM | c.7035A>C p.L2345F | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV53737109; called by muse, mutect2, varscan2
- ATP10B | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs752814719, COSV59148132; called by muse, mutect2, varscan2
- ATP10D | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs192815760, COSV56705999; called by muse, mutect2, varscan2
- ATP11C | c.2840A>G p.K947R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59561961; called by muse, varscan2
- ATP12A | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 225/489 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV54514659; called by muse, mutect2, varscan2
- ATP13A1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770383402, COSV52284598; called by muse, mutect2, varscan2
- ATP13A1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs763096515, COSV52284614; called by muse, mutect2, varscan2
- ATP13A3 | c.2109G>T p.Q703H | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV55463223; called by muse, mutect2, varscan2
- ATP13A3 | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 95/211 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV55463230; called by muse, mutect2, varscan2
- ATP13A4 | c.2468G>T p.R823I | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61318545; called by muse, mutect2, varscan2
- ATP13A4 | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55068071; called by muse, mutect2
- ATP1A2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs374501280; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ATP1A3 | c.1277A>G p.H426R (on ENST00000545399 / NM_001256214.2; = p.H413R on NM_152296.5) | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782747161, COSV57486684; called by muse, mutect2, varscan2
- ATP1A4 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs759849579, COSV63626077; called by muse, mutect2, varscan2
- ATP1B1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 148/327 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs774828234, COSV63179139; called by muse, mutect2, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV53806099; called by muse, mutect2, varscan2
- ATP2B1 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 164/355 reads (46%) | catalogued as COSV53805728; called by muse, mutect2, varscan2
- ATP2B3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as rs781827206, COSV54843028; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP5F1A | c.1533C>A p.F511L | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.1); catalogued as COSV56360063; called by muse, mutect2, varscan2
- ATP5F1A | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs765711330, COSV56360072; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 143/361 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV57748593; called by muse, mutect2, varscan2
- ATP6V0A4 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 110/251 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV59474144; called by muse, mutect2, varscan2
- ATP6V1C2 | c.124T>G p.F42V | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs757706515, COSV55359226; called by muse, mutect2, varscan2
- ATP6V1H | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV100778607; called by muse, mutect2
- ATP7A | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV58444738; called by muse, mutect2, varscan2
- ATP7A | c.3200G>T p.R1067I | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.12); catalogued as COSV58444749; called by muse, mutect2, varscan2
- ATP8A1 | c.2215G>T p.D739Y | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52532242; called by muse, mutect2, varscan2
- ATP8A1 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 283/637 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.597); catalogued as COSV52532258; called by muse, mutect2, varscan2
- ATP8A2 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 163/384 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54945829; called by muse, mutect2, varscan2
- ATP8B1 | c.2762C>T p.S921L | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367575213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B1 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 195/424 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV52174377; called by muse, mutect2, varscan2
- ATP8B4 | c.1319C>A p.S440Y | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV52713075; called by muse, mutect2, varscan2
- ATR | c.4138G>T p.D1380Y | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV63385516; called by muse, mutect2, varscan2
- ATRIP | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57176645; called by muse, mutect2, varscan2
- ATRNL1 | c.2582A>C p.N861T | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV58081921; called by muse, mutect2, varscan2
- ATRX | c.7090C>A p.L2364I | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV64874510, COSV64874580; called by muse, mutect2, varscan2
- ATRX | c.5216G>A p.R1739Q | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV64874516; called by muse, varscan2
- ATRX | c.3512G>T p.R1171I | Missense Mutation (SNP) | VAF 90/514 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV64874523; called by muse, mutect2, varscan2
- ATRX | c.1584T>G p.I528M | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV64874530; called by muse, mutect2, varscan2
- ATRX | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 249/573 reads (43%) | catalogued as COSV64869496; called by muse, mutect2, varscan2
- ATXN2 | c.1942G>T p.E648* (on ENST00000550104; = p.E488* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 93/223 reads (42%) | catalogued as COSV66482468; called by muse, varscan2
- ATXN2 | c.1895G>A p.R632Q (on ENST00000550104; = p.R472Q on NM_002973.4) | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV66482110; called by muse, varscan2
- ATXN3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 152/388 reads (39%) | catalogued as COSV61494145; called by muse, mutect2, varscan2
- ATXN7 | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV55749578; called by muse, mutect2, varscan2
- ATXN7L2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1477912338, COSV63992186; called by muse, mutect2, varscan2
- AUP1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 110/276 reads (40%) | catalogued as rs968068750, COSV57816810; called by muse, mutect2, varscan2
- AURKC | c.617T>C p.L206S (on ENST00000302804 / NM_001015878.2; = p.L172S on NM_003160.3) | Missense Mutation (SNP) | VAF 110/266 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57137743; called by muse, mutect2, varscan2
- AVPR1A | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV54546173, COSV54547962; called by muse, mutect2, varscan2
- AXDND1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.942); catalogued as COSV62641382; called by muse, mutect2, varscan2
- B3GALT1 | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100002512; called by muse, mutect2
- B3GALT5 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58198442; called by muse, mutect2, varscan2
- B4GALNT1 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV57542213; called by muse, varscan2
- B4GALT3 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs745448974, COSV60526936; called by muse, mutect2, varscan2
- BAG3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs746454994, COSV64841721; called by muse, mutect2, varscan2
- BAG6 | c.3200T>C p.I1067T (on ENST00000676571; = p.I1020T on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99276473; called by muse, mutect2
- BAHD1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747501429, COSV69083810; called by muse, mutect2, varscan2
- BAIAP2 | c.1287C>A p.F429L | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV58334414; called by muse, mutect2, varscan2
- BAIAP2L1 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1370693898, COSV50055256; called by muse, varscan2
- BAIAP3 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs760205376, COSV50103879, COSV99136177; called by muse, mutect2, varscan2
- BANK1 | c.355A>C p.K119Q | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV59841127; called by muse, mutect2, varscan2
- BARHL1 | c.188C>A p.T63N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.014); catalogued as COSV55037378; called by muse, varscan2
- BARX1 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54158856, COSV54159486; called by muse, mutect2, varscan2
- BAZ2B | c.5719C>T p.R1907C | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370717896; called by muse, mutect2, varscan2
- BBS10 | c.1513C>A p.P505T | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV101283351, COSV67913150; called by muse, mutect2
- BBS10 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53880468, COSV53880698; called by muse, mutect2, varscan2
- BBS2 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as CM104184, COSV55325908; called by muse, mutect2, varscan2
- BBS7 | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52655333; called by muse, mutect2
- BBS9 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV54163090; called by muse, mutect2, varscan2
- BCAT1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373461769; called by muse, mutect2, varscan2
- BCAT1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV53909909; called by muse, mutect2, varscan2
- BCHE | c.1724T>G p.F575C | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52255384; called by muse, varscan2
- BCHE | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 90/184 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV52255400; called by muse, mutect2, varscan2
- BCKDK | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV54891291; called by muse, mutect2, varscan2
- BCL2L2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.076); catalogued as rs745978918, COSV51635366; called by muse, mutect2, varscan2
- BCL6B | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV53427305; called by muse, mutect2, varscan2
- BCL9L | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs773057514, COSV52683368; called by muse, mutect2, varscan2
- BCLAF3 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 262/606 reads (43%) | catalogued as COSV61413630; called by muse, mutect2, varscan2
- BCO2 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV54784074; called by muse, mutect2, varscan2
- BCOR | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100652930; called by muse, mutect2
- BCORL1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs201232537, COSV54393693; called by muse, mutect2, varscan2
- BDH2 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 209/477 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56478116; called by muse, mutect2, varscan2
- BDNF | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs750030464, COSV100151992, COSV59234276; called by muse, mutect2, varscan2
- BEND2 | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV66215548; called by muse, mutect2, varscan2
- BEND7 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.359); catalogued as rs748963672, COSV61988268; called by muse, mutect2, varscan2
- BEST1 | c.568A>G p.N190D | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57120347; called by muse, mutect2, varscan2
- BEX3 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 165/413 reads (40%) | catalogued as COSV55420954, COSV55421135; called by muse, mutect2, varscan2
- BFSP1 | c.535-1G>T p.X179_splice | Splice Site (SNP) | VAF 127/261 reads (49%) | catalogued as COSV64899915; called by muse, mutect2, varscan2
- BGN | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1156728437, COSV59036355; called by muse, mutect2, varscan2
- BHLHE40 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV56575250, COSV56576604; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN2 | c.203T>G p.L68R | Missense Mutation (SNP) | VAF 65/300 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57204788; called by muse, mutect2, varscan2
- BIRC6 | c.2763A>C p.E921D | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV70197744; called by muse, mutect2, varscan2
- BIRC6 | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1158247243, COSV70197748; called by muse, varscan2
- BLM | c.4187T>A p.L1396* | Nonsense Mutation (SNP) | VAF 94/215 reads (44%) | catalogued as COSV61923311; called by muse, varscan2
- BLOC1S5 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | catalogued as COSV55241110; called by muse, mutect2, varscan2
- BLOC1S6 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 161/384 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779791657, COSV55035249; called by muse, mutect2, varscan2
- BMP10 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs754341746, COSV54894849; called by muse, mutect2, varscan2
- BMP2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV66577480; called by muse, varscan2
- BMP2K | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1168437955, COSV58593913; called by muse, mutect2, varscan2
- BMP5 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 37/229 reads (16%) | catalogued as COSV63701649, COSV63702350; called by muse, mutect2, varscan2
- BMPR1A | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 110/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755372473, COSV100923331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.2027A>G p.N676S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV65808557; called by muse, mutect2, varscan2
- BMT2 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51775822, COSV51775977, COSV99774725; called by muse, mutect2, varscan2
- BMX | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59590998; called by muse, mutect2, varscan2
- BNC2 | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.978); catalogued as rs138000896; called by muse, mutect2, varscan2
- BNC2 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 139/319 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV66144480; called by muse, mutect2, varscan2
- BNC2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66144492; called by muse, mutect2, varscan2
- BOD1L1 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 241/580 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777815085, COSV50009351, COSV99240547; called by muse, mutect2, varscan2
- BPHL | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778150605, COSV66743327; called by muse, mutect2, varscan2
- BPIFA1 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV100845632; called by muse, mutect2
- BPIFA1 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV62824203; called by muse, mutect2
- BPIFA2 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99487771; called by muse, mutect2, varscan2
- BPIFB4 | c.1742A>G p.N581S | Missense Mutation (SNP) | VAF 136/308 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64950978; called by muse, mutect2, varscan2
- BPIFC | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 147/323 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55911765, COSV55915220; called by muse, mutect2, varscan2
- BPTF | c.2411A>C p.K804T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58835097; called by muse, mutect2, varscan2
- BRCA1 | c.2885A>C p.E962A | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV58787796; called by muse, mutect2, varscan2
- BRCA1 | c.1682C>A p.S561Y | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58787823, COSV58803138; called by muse, varscan2
- BRCA2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as rs1464889530, COSV66451270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.4146A>C p.E1382D | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as CD1313770, COSV66451811; called by muse, varscan2
- BRCA2 | c.4790C>A p.S1597Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.067); catalogued as rs876660146, COSV66451830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.5354C>T p.T1785I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV66451837; called by muse, mutect2, varscan2
- BRCA2 | c.6803G>T p.R2268I | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as CM124686, COSV66447497, COSV66451846; called by muse, mutect2, varscan2
- BRCA2 | c.7253G>T p.R2418I | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV66451853, COSV66457211, COSV66463790; called by muse, mutect2, varscan2
- BRD1 | c.2645G>A p.R882Q (on ENST00000216267 / NM_001349940.1; = p.R1013Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs762473117, COSV53456206; called by muse, mutect2, varscan2
- BRD1 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as rs751309590, COSV53456222; called by muse, mutect2, varscan2
- BRD8 | c.3113G>A p.S1038N | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.474); catalogued as rs1466051679, COSV54725587; called by muse, mutect2, varscan2
- BRD8 | c.2321G>A p.R774H (on ENST00000254900 / NM_139199.2; = p.R847H on NM_006696.4) | Missense Mutation (SNP) | VAF 93/187 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50146651; called by muse, mutect2, varscan2
- BRINP2 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64176827; called by muse, mutect2, varscan2
- BRIP1 | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578022079, COSV51997487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.93+2T>C p.X31_splice | Splice Site (SNP) | VAF 20/260 reads (8%) | catalogued as COSV99369372; called by muse, mutect2
- BRPF1 | c.1840C>T p.L614F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57404213; called by muse, varscan2
- BRS3 | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 205/452 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV65710715, COSV65710851; called by muse, mutect2, varscan2
- BRSK1 | c.501A>C p.K167N | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV58665764; called by muse, mutect2, varscan2
- BRWD1 | c.5789G>T p.R1930I | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as COSV60894517; called by muse, mutect2, varscan2
- BRWD1 | c.2569A>C p.S857R | Missense Mutation (SNP) | VAF 48/462 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100312923; called by muse, mutect2, varscan2
- BRWD3 | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 27/601 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100956347, COSV64750551; called by muse, mutect2
- BSN | c.6802C>T p.P2268S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV56515788; called by muse, mutect2, varscan2
- BSN | c.11764T>C p.F3922L | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV56515798, COSV99607262; called by muse, varscan2
- BTAF1 | c.2635A>C p.K879Q | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV56432049, COSV56437392; called by muse, mutect2, varscan2
- BTAF1 | c.5346G>T p.E1782D | Missense Mutation (SNP) | VAF 166/390 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV56432064; called by muse, mutect2, varscan2
- BTBD11 | c.2837C>A p.P946Q (on ENST00000280758 / NM_001018072.2; = p.P483Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as COSV99774801; called by muse, mutect2
- BTBD3 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs535169870, COSV54778704; called by muse, mutect2, varscan2
- BTBD6 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1006178636, COSV59267853; called by muse, mutect2, varscan2
- BTBD7 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV58284814; called by muse, mutect2, varscan2
- BTN2A1 | c.344T>G p.I115S | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV57002885; called by muse, mutect2, varscan2
- BTN2A1 | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 24/533 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV100438392; called by muse, mutect2
- BUB1 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs867863036, COSV57062533; called by muse, mutect2, varscan2
- BUD23 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs143474628; called by muse, mutect2, varscan2
- C10orf120 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1361230854, COSV61491809; called by muse, mutect2, varscan2
- C10orf90 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs772583912, COSV52952791, COSV52965613; called by muse, mutect2, varscan2
- C11orf1 | c.150T>G p.F50L | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52787947; called by muse, mutect2, varscan2
- C11orf16 | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV58166883; called by muse, mutect2, varscan2
- C11orf80 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60928760; called by muse, mutect2, varscan2
- C12orf4 | c.1115T>C p.V372A | Missense Mutation (SNP) | VAF 150/348 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54206462; called by muse, varscan2
- C12orf4 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV54206233; called by muse, mutect2, varscan2
- C12orf50 | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 196/453 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.23); catalogued as COSV53894512; called by muse, mutect2, varscan2
- C16orf71 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs765725967, COSV58508426; called by muse, mutect2, varscan2
- C18orf21 | c.629T>A p.F210Y | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52449277; called by muse, mutect2, varscan2
- C1QL1 | c.522C>A p.Y174* | Nonsense Mutation (SNP) | VAF 31/93 reads (33%) | catalogued as COSV53646895; called by muse, mutect2, varscan2
- C1QTNF2 | c.205C>T p.R69C (on ENST00000393975; = p.R24C on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); catalogued as rs762662420, COSV67432573; called by muse, varscan2
- C1orf131 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 195/465 reads (42%) | catalogued as COSV59642144; called by muse, mutect2, varscan2
- C1orf174 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 73/133 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64365758; called by muse, mutect2, varscan2
- C1orf198 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs771310728, COSV64175070; called by muse, mutect2, varscan2
- C1orf35 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs574841558, COSV99683051; called by muse, varscan2
- C21orf91 | c.734T>G p.F245C (on ENST00000284881 / NM_001100420.2; = p.F244C on NM_017447.4) | Missense Mutation (SNP) | VAF 95/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427621177, COSV53032693; called by muse, mutect2, varscan2
- C2CD5 | c.1737G>A p.A579= | Splice Region (SNP) | VAF 116/267 reads (43%) | catalogued as rs760473058, COSV61723983; called by muse, mutect2, varscan2
- C2CD5 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs762976489, COSV61723991; called by muse, mutect2, varscan2
- C2CD6 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs779021017, COSV53791293; called by muse, mutect2
- C2orf50 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141429224, COSV67510550; called by muse, mutect2, varscan2
- C2orf78 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as COSV68517176; called by muse, mutect2, varscan2
- C2orf78 | c.2327C>A p.S776Y | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101280900, COSV101280904; called by muse, mutect2, varscan2
- C3orf18 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV51750268; called by muse, mutect2, varscan2
- C3orf38 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV59627722; called by muse, mutect2
- C4orf51 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 51/219 reads (23%) | catalogued as rs1484682694, COSV71264040; called by muse, mutect2, varscan2
- C5 | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as rs143353740; called by muse, mutect2, varscan2
- C5 | c.3308C>A p.S1103Y | Missense Mutation (SNP) | VAF 88/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV56326067, COSV56326209; called by muse, mutect2, varscan2
- C6 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 125/269 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV54708359; called by muse, mutect2, varscan2
- C7orf25 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1003393016, COSV63273458; called by muse, mutect2, varscan2
- C8A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 159/351 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940831429, COSV63483165; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 98/532 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- C9 | c.926G>T p.R309I | Missense Mutation (SNP) | VAF 155/342 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54675807; called by muse, mutect2, varscan2
- C9 | c.700A>C p.N234H | Missense Mutation (SNP) | VAF 148/319 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54675814; called by muse, mutect2, varscan2
- C9 | c.367A>G p.N123D | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.471); catalogued as rs773348076, COSV54675819; called by muse, mutect2, varscan2
- C9orf153 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV59251069; called by muse, mutect2, varscan2
- CA5B | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV59416130; called by muse, mutect2, varscan2
- CA8 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs201131573, COSV58771470; called by muse, mutect2, varscan2
- CA9 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs776382092, COSV65675277; called by muse, mutect2, varscan2
- CABLES1 | c.1580C>T p.A527V (on ENST00000256925 / NM_001100619.2; = p.A262V on NM_138375.2) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as rs529533048, COSV56932308; called by muse, mutect2, varscan2
- CABP1 | c.802G>A p.E268K (on ENST00000316803 / NM_001033677.1; = p.E65K on NM_004276.5) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1328676871, COSV56458203; called by muse, mutect2, varscan2
- CABP5 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV53152600; called by muse, varscan2
- CACHD1 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); catalogued as COSV99261517; called by muse, mutect2
- CACHD1 | c.3268A>G p.M1090V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.354); catalogued as COSV51551551; called by muse, mutect2, varscan2
- CACNA1A | c.803C>A p.S268Y | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.904); catalogued as COSV64194911; called by muse, mutect2, varscan2
- CACNA1A | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as rs886042230, COSV64194925; called by muse, mutect2, varscan2
- CACNA1A | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100801096; called by muse, mutect2
- CACNA1B | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53121283; called by muse, mutect2, varscan2
- CACNA1B | c.1274G>T p.R425I | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV53121291; called by muse, mutect2, varscan2
- CACNA1B | c.4667C>T p.A1556V | Missense Mutation (SNP) | VAF 174/397 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.19); catalogued as rs199500748, COSV53121317; called by muse, varscan2
- CACNA1C | c.2888C>A p.S963Y | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59707867, COSV59721607; called by muse, mutect2, varscan2
- CACNA1C | c.3104T>C p.V1035A | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100215713; called by muse, mutect2
- CACNA1C | c.6385G>A p.V2129I (on ENST00000399634 / NM_001167625.1; = p.V2058I on NM_000719.7) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as COSV59708682; called by muse, mutect2, varscan2
- CACNA1C | c.6571C>T p.R2191W (on ENST00000399634 / NM_001167625.1; = p.R2120W on NM_000719.7) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV59708706; called by muse, mutect2, varscan2
- CACNA1D | c.5390G>T p.R1797I (on ENST00000350061 / NM_001128840.3; = p.R1817I on NM_000720.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.013); catalogued as COSV55443271; called by muse, mutect2, varscan2
- CACNA1S | c.4601G>A p.R1534Q | Missense Mutation (SNP) | VAF 116/243 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs891244994, COSV62938443; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62938447; called by muse, mutect2, varscan2
- CACNA2D3 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.088); catalogued as rs748524522, COSV55528344; called by muse, mutect2, varscan2
- CACNA2D4 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759766082, COSV54947860, COSV99765467; called by muse, mutect2, varscan2
- CACNA2D4 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.519); catalogued as COSV54943956, COSV54947872; called by muse, mutect2, varscan2
- CACNB4 | c.910A>T p.R304* | Nonsense Mutation (SNP) | VAF 175/356 reads (49%) | catalogued as rs1553747022, COSV52392045; called by muse, mutect2, varscan2
- CACNG4 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50924597, COSV50925372; called by muse, mutect2, varscan2
- CAD | c.5260C>A p.L1754M | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV53024397, COSV53025530; called by muse, mutect2, varscan2
- CADM3 | c.295A>G p.N99D (on ENST00000368125 / NM_001127173.3; = p.N133D on NM_021189.5) | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV63684872; called by muse, mutect2, varscan2
- CADPS | c.3148T>C p.W1050R | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as COSV51874356; called by muse, mutect2, varscan2
- CADPS2 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 183/366 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV57357683; called by muse, mutect2, varscan2
- CALD1 | c.1455G>T p.K485N (on ENST00000361675 / NM_033138.4; = p.K230N on NM_004342.7) | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62646827; called by muse, mutect2, varscan2
- CALM2 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 248/522 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV55399155; called by muse, varscan2
- CALM2 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 158/332 reads (48%) | catalogued as COSV55399209; called by muse, varscan2
- CALML4 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as COSV61205890; called by muse, mutect2, varscan2
- CALN1 | c.503C>T p.S168L (on ENST00000329008 / NM_001017440.3; = p.S210L on NM_031468.4) | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs143545775; called by muse, mutect2, varscan2
- CALR | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200421584, COSV57122161; called by muse, mutect2, varscan2
- CALR3 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV54169199; called by muse, mutect2, varscan2
- CALU | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 127/280 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50821479; called by muse, mutect2, varscan2
- CAMK1D | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs148446769; called by muse, mutect2, varscan2
- CAMK2A | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62245874; called by muse, mutect2, varscan2
- CAMK4 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as COSV56668183; called by muse, mutect2, varscan2
- CAMSAP1 | c.3999G>T p.E1333D | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV56721094; called by muse, mutect2, varscan2
- CAMSAP1 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1265391740, COSV56719110; called by muse, mutect2, varscan2
- CAMSAP1 | c.2491A>G p.K831E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as COSV56721121; called by muse, mutect2, varscan2
- CAMTA1 | c.3836C>A p.S1279Y | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV57893042; called by muse, mutect2, varscan2
- CANX | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 145/300 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV56003610; called by muse, mutect2, varscan2
- CAP2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 110/236 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57731185; called by muse, mutect2, varscan2
- CAP2 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 202/441 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57731197; called by muse, mutect2, varscan2
- CAPN11 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760085717, COSV67237080; called by muse, mutect2, varscan2
- CAPN13 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs370602522; called by muse, mutect2, varscan2
- CAPN5 | c.739G>T p.D247Y (on ENST00000456580; = p.D207Y on NM_004055.5) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs367724731, COSV53687605; called by muse, mutect2, varscan2
- CAPN6 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 250/529 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV60694529; called by muse, mutect2, varscan2
- CAPN9 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV55232544; called by muse, mutect2, varscan2
- CAPRIN2 | c.2656A>C p.N886H | Missense Mutation (SNP) | VAF 183/420 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV51831775; called by muse, mutect2, varscan2
- CAPRIN2 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 299/691 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs756534335, COSV51831573, COSV99195654; called by muse, mutect2, varscan2
- CAPRIN2 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV51830686; called by muse, mutect2, varscan2
- CAPRIN2 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 44/419 reads (11%) | catalogued as COSV51831800; called by muse, mutect2, varscan2
- CARD11 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs770667388, COSV101210957, COSV67797644; called by muse, mutect2, varscan2
- CARD6 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54565502; called by muse, varscan2
- CARF | c.1820C>A p.S607Y | Missense Mutation (SNP) | VAF 101/211 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs1559289266, COSV57547173; called by muse, mutect2, varscan2
- CARMIL1 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs1476173801, COSV61516072; called by muse, mutect2, varscan2
- CARMIL2 | c.3667A>G p.S1223G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54666830; called by muse, mutect2, varscan2
- CARS2 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as rs1232480983, COSV57285285; called by muse, mutect2, varscan2
- CASC3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183006262, COSV52866935; called by muse, mutect2, varscan2
- CASK | c.1660A>C p.K554Q | Missense Mutation (SNP) | VAF 151/324 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.73); catalogued as COSV59364706; called by muse, mutect2, varscan2
- CASKIN1 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58871346; called by muse, mutect2, varscan2
- CASP1 | c.210A>C p.Q70H | Missense Mutation (SNP) | VAF 130/514 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV62056279; called by muse, mutect2, varscan2
- CASP10 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as COSV53777494; called by muse, mutect2, varscan2
- CASP8 | c.155G>T p.R52I | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV51845596; called by muse, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, varscan2
- CASP8AP2 | c.2576C>A p.P859H | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52744987, COSV99386782; called by muse, mutect2, varscan2
- CASP8AP2 | c.2753A>C p.K918T | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV99386784; called by muse, mutect2, varscan2
- CASQ2 | c.1196A>C p.E399A | Missense Mutation (SNP) | VAF 284/645 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as rs375286334; called by muse, varscan2
- CASQ2 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV54769622; called by muse, mutect2, varscan2
- CATIP | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs796331616, COSV56822442; called by muse, mutect2, varscan2
- CATSPER1 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV56409938; called by muse, mutect2, varscan2
- CATSPER2 | c.991A>C p.I331L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV58660576; called by muse, mutect2, varscan2
- CATSPERB | c.2802C>A p.F934L | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99830865; called by muse, mutect2
- CAV1 | c.266T>C p.F89S | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV61952975; called by muse, mutect2, varscan2
- CAV2 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56063830, COSV99760773; called by muse, mutect2, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by muse, mutect2, varscan2
- CBLB | c.2441T>G p.F814C | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV51424513; called by muse, mutect2, varscan2
- CBWD2 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 84/489 reads (17%) | catalogued as COSV52073724; called by muse, mutect2, varscan2
- CBX7 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53358725; called by mutect2, varscan2
- CC2D2A | c.4472C>T p.A1491V | Missense Mutation (SNP) | VAF 21/234 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1335588110, COSV101052670; called by muse, mutect2
- CCDC102B | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 140/297 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as rs867241481, COSV60133455; called by muse, mutect2, varscan2
- CCDC112 | c.899A>C p.K300T | Missense Mutation (SNP) | VAF 206/487 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV65472928; called by muse, varscan2
- CCDC112 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 328/712 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV65472726; called by muse, varscan2
- CCDC121 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as COSV53114026, COSV53114740; called by muse, mutect2, varscan2
- CCDC122 | c.111A>C p.Q37H | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55709087; called by muse, mutect2, varscan2
- CCDC136 | c.18G>A p.G6= | Splice Region (SNP) | VAF 23/52 reads (44%) | catalogued as COSV52798524; called by muse, mutect2, varscan2
- CCDC141 | c.2598G>T p.K866N | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV55371659, COSV55371745; called by muse, mutect2, varscan2
- CCDC144A | c.1501A>C p.K501Q | Missense Mutation (SNP) | VAF 189/452 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV60697650; called by muse, mutect2, varscan2
- CCDC146 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as COSV53546651; called by muse, mutect2, varscan2
- CCDC15 | c.1316G>A p.S439N | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61081119; called by muse, mutect2, varscan2
- CCDC150 | c.2683C>A p.Q895K | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV55873463; called by muse, mutect2, varscan2
- CCDC158 | c.3224G>A p.S1075N | Missense Mutation (SNP) | VAF 265/579 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV66355333; called by muse, mutect2, varscan2
- CCDC160 | c.202T>A p.F68I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV66251461; called by muse, mutect2, varscan2
- CCDC170 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53339395, COSV53343411; called by muse, mutect2, varscan2
- CCDC171 | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 44/89 reads (49%) | catalogued as COSV52638937; called by muse, mutect2, varscan2
- CCDC171 | c.2547A>C p.K849N | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52638947; called by muse, mutect2, varscan2
- CCDC173 | c.567G>T p.L189F | Missense Mutation (SNP) | VAF 229/498 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV69572726; called by muse, mutect2, varscan2
- CCDC18 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 85/177 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs776122584, COSV58142484; called by muse, mutect2, varscan2
- CCDC181 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 61/500 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.517); catalogued as COSV63156153, COSV63156501; called by muse, mutect2, varscan2
- CCDC191 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55671339; called by muse, mutect2, varscan2
- CCDC27 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as rs758447306, COSV53898749; called by muse, mutect2, varscan2
- CCDC30 | c.916C>T p.R306* (on ENST00000340612; = p.R263* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 115/272 reads (42%) | catalogued as rs780702656, COSV59604704; called by muse, mutect2, varscan2
- CCDC30 | c.1454T>G p.I485S (on ENST00000340612; = p.I442S on NM_001080850.3) | Missense Mutation (SNP) | VAF 150/334 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV59605608; called by muse, mutect2, varscan2
- CCDC30 | c.1789A>G p.I597V (on ENST00000340612; = p.I554V on NM_001080850.3) | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.258); catalogued as rs761732021, COSV59605612; called by muse, mutect2, varscan2
- CCDC39 | c.845G>T p.R282I | Missense Mutation (SNP) | VAF 276/627 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV56481826, COSV56492841; called by muse, mutect2, varscan2
- CCDC39 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 20/412 reads (5%) | catalogued as COSV56477668, COSV99867362; called by muse, mutect2
- CCDC40 | c.2194T>G p.F732V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV66473972; called by muse, mutect2, varscan2
- CCDC42 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 114/312 reads (37%) | catalogued as COSV53448504; called by muse, mutect2, varscan2
- CCDC54 | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780655666, COSV53758399; called by muse, mutect2, varscan2
- CCDC6 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 146/362 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as COSV54055879; called by muse, mutect2, varscan2
- CCDC60 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as COSV100554655; called by muse, varscan2
- CCDC63 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs761590144, COSV57527007; called by muse, mutect2, varscan2
- CCDC65 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as rs763399234, COSV57195213; called by muse, mutect2, varscan2
- CCDC66 | c.710T>C p.I237T (on ENST00000394672 / NM_001353147.1; = p.I203T on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/242 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58302877; called by muse, mutect2, varscan2
- CCDC7 | c.3888A>C p.E1296D | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.99); catalogued as COSV56540113; called by muse, mutect2, varscan2
- CCDC78 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs200893683, COSV52401632; called by muse, mutect2, varscan2
- CCDC82 | c.903A>C p.Q301H | Missense Mutation (SNP) | VAF 275/616 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV53592888; called by muse, mutect2, varscan2
- CCDC83 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99721491; called by muse, mutect2
- CCDC83 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54701092; called by muse, mutect2, varscan2
- CCDC86 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs370580113; called by muse, mutect2, varscan2
- CCDC88A | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 184/450 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1478936546, COSV55059641; called by muse, mutect2, varscan2
- CCDC88A | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 69/168 reads (41%) | catalogued as COSV55059652; called by muse, mutect2, varscan2
- CCDC88A | c.1421A>C p.K474T | Missense Mutation (SNP) | VAF 207/513 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as COSV55059665; called by muse, mutect2, varscan2
- CCDC90B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 220/556 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs148744063, COSV52623726; called by muse, mutect2, varscan2
- CCDC97 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs567042490, COSV54189948; called by mutect2, varscan2
- CCDC9B | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372833743, COSV66875169; called by muse, mutect2, varscan2
6,073 further variants in this file (4,654 protein-altering or splice-affecting, 1,294 silent, 125 other) are not listed here.
